Somatic mutation profile of tumor specimen TARGET-10-PARJZZ-04A (aliquot TARGET-10-PARJZZ-04A-01D) from TARGET case TARGET-10-PARJZZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,538 days).
Specimen TARGET-10-PARJZZ-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9806c4d1-faac-4c9e-9cc2-e832575b40a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARJZZ-10A (Blood Derived Normal), aliquot TARGET-10-PARJZZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08cac0cf-938a-42da-8496-e214d0bff1ce

The open-access MAF lists 27 somatic variants for this specimen: 17 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 9, Intron 1, Frame Shift Del 1, Frame Shift Ins 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs730880472, COSV55534139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BICRA | c.2746C>T p.P916S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs374376150; called by muse, mutect2, varscan2
- CNTN6 | c.2257del p.V753Cfs*37 | Frame Shift Del (DEL) | VAF 86/225 reads (38%) | catalogued as COSV63192743; called by mutect2, pindel*, varscan2
- DUSP8 | c.569_574del p.V190_N192delinsD | In Frame Del (DEL) | VAF 27/97 reads (28%) | catalogued as COSV59031644; called by mutect2, pindel, varscan2
- HSH2D | c.608T>G p.L203R | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53738820; called by muse, mutect2, varscan2
- KMT2D | c.6656_6657insAGTACGTTAGTA p.G2219_A2220insVR* | Nonsense Mutation (INS) | VAF 26/60 reads (43%) | catalogued as COSV56493533; called by mutect2, pindel
- NEBL | c.2485G>A p.V829M | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.372); catalogued as rs727504979, COSV65806409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NT5C2 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 75/250 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as rs1057519866, COSV58414509; ClinVar: not provided; called by muse, mutect2, varscan2
- PANK2 | c.181A>G p.R61G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs1440283414; called by muse, varscan2
- POLRMT | c.3352G>A p.G1118S | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs143273183; called by muse, mutect2, varscan2
- PYHIN1 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.83); catalogued as COSV63724378; called by muse, mutect2, varscan2
- TFF3 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52295226; called by muse, mutect2, varscan2
- TNKS | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs753349258, COSV60067630; called by muse, mutect2, varscan2
- USH2A | c.3763A>C p.S1255R | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV56450474; called by muse, mutect2, varscan2
- ZNF716 | c.341G>T p.R114I | Missense Mutation (SNP) | VAF 11/331 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs782102491, COSV70780784; called by muse, mutect2
- HRNR | c.5758T>A p.S1920T | Missense Mutation (SNP) | VAF 44/528 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.043); called by muse, mutect2
- LOXL2 | c.1901_1902insCCCCCTCCCTAGGGGGT p.F635Pfs*13 | Frame Shift Ins (INS) | VAF 52/247 reads (21%) | called by mutect2, pindel, varscan2
- ATP2B2 | c.2550C>T p.I850= (on ENST00000352432; = p.I816= on NM_001683.5) | Silent (SNP) | VAF 46/149 reads (31%) | catalogued as rs111706887, COSV59496858; called by muse, mutect2, varscan2
- COL2A1 | c.3756C>T p.D1252= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs377079894; ClinVar: likely benign; called by muse, mutect2, varscan2
- FRMD4A | c.942A>G p.Q314= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as COSV52738186; called by muse, varscan2
- MADD | c.4119A>T p.T1373= | Silent (SNP) | VAF 48/173 reads (28%) | catalogued as COSV60630415; called by muse, mutect2, varscan2
- MVB12B | c.327C>T p.N109= | Silent (SNP) | VAF 39/138 reads (28%) | catalogued as rs769776964, COSV63260506; called by muse, mutect2, varscan2
- PCDH11Y | c.597C>T p.D199= (on ENST00000400457 / NM_032973.2; = p.D188= on NM_032971.3) | Silent (SNP) | VAF 59/96 reads (61%) | catalogued as COSV53084614; called by muse, mutect2, varscan2
- SLC35B1 | c.522G>A p.P174= (on ENST00000649906; = p.P137= on NM_005827.4) | Silent (SNP) | VAF 52/161 reads (32%) | catalogued as rs139526275; called by muse, mutect2, varscan2
- TCF7L1 | c.303T>C p.Y101= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- ZNF618 | c.2373G>A p.A791= (on ENST00000374126 / NM_001318042.2; = p.A698= on NM_133374.2) | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs147007253, COSV55931344; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23291G>A | Intron (SNP) | VAF 8/29 reads (28%) | catalogued as rs745945267, COSV59384944; called by muse, mutect2, varscan2
